TCGA case TCGA-F4-6806 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bab21810-f51b-421e-a87f-1f1136cbc77a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 59 years; Vital status: Alive.

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 59.2 years (21,625 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,260 days (3.4 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan; Days to treatment start: 42 days; Days to treatment end: 158 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 42 days; Days to treatment end: 158 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Mitomycin; Days to treatment start: 173 days; Days to treatment end: 263 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Days to treatment start: 361 days; Days to treatment end: 412 days (1.1 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Oxaliplatin; Days to treatment start: 641 days (1.8 years); Days to treatment end: 760 days (2.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 641 days (1.8 years); Days to treatment end: 760 days (2.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Days to treatment start: 760 days (2.1 years); Days to treatment end: 883 days (2.4 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Days to treatment start: 1,161 days (3.2 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Days to treatment start: 1,161 days (3.2 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 60.1 years (21,961 days); Days to diagnosis: 336 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 336 days; Residual disease: R0; Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 60.9 years (22,238 days); Days to diagnosis: 613 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
4. Diagnosis record without a diagnosis name: Tissue or organ of origin: Lung, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.3 years (22,757 days); Days to diagnosis: 1,132 days (3.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (7 entries)
- Days to follow up: 20 days; Disease response: Tumor Free.
- Day 336 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 336 days.
- Days to follow up: 481 days (1.3 years); Disease response: Tumor Free.
- Day 613 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 613 days (1.7 years).
- Days to follow up: 900 days (2.5 years); Disease response: With Tumor.
- Day 1,132 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 1,132 days (3.1 years).
- Days to follow up: 1,260 days (3.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 172 cm; BMI: 23.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F4-6806-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-F4-6806-01A-01-TS1: Section location: Top; Percent tumor cells: 77; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 8; Percent stromal cells: 10.
  Slide TCGA-F4-6806-01A-01-BS1: Section location: Bottom; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-F4-6806-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F4-6806-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Microsatellite instability: No; Loci tested count: 0; Loci abnormal count: 0; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 10: Pharmaceutical therapy drug name: Camptosar.
- Drug treatment 12: Pharmaceutical therapy drug name: Avastin.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,260 days; disease-specific survival: no event (censored), 1,260 days; disease-free interval: event (new tumor event after initially disease-free), 336 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 336 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F4-6806-01A-11D-1834-01): tumor purity 0.71, ploidy 2.02, whole-genome doublings 0.
